Gene-level copy-number profile of tumor specimen ALCH-B015-TTP1-A from ALCHEMIST case ALCH-B015, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma in situ, NOS; Age at diagnosis: 60.9 years (22,240 days).
Specimen ALCH-B015-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 32b19952-934d-4a48-84d7-4ed8498e78bd.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B015-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,229 have no estimate.
https://portal.gdc.cancer.gov/files/a8c67b8e-1692-4e7e-a403-01ec1e21dc7f

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 52; copy number 1: 480; copy number 2: 19,840; copy number 3: 19,906; copy number 4: 12,009; copy number 5: 4,835; copy number 6: 778; copy number 7: 70; copy number 8: 199; copy number 9: 8; copy number 10: 28; copy number 11: 42; copy number 13: 2; copy number 14: 6; copy number 15: 31; copy number 20: 34; copy number 22: 35; copy number 23: 39.

Homozygous deletions (total copy number 0; autosomes only): 52 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:49,486,926–49,523,857, 4 genes: AC119751.3, ANKRD20A17P, AC119751.5, AC119751.2.
- chr4:49,579,833–49,589,529, 2 genes: AC119751.4, SNX18P25.
- chr15:25,176,832–25,250,940, 41 genes (within-gene range 0–1): SNORD115-4, SNORD115-5, SNORD115-6, SNORD115-7, SNORD115-8, SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25, SNORD115-26, SNORD115-27, SNORD115-28, SNORD115-29, SNORD115-30, SNORD115-31, SNORD115-32, SNORD115-33, SNORD115-34, SNORD115-35, SNORD115-36, SNORD115-37, SNORD115-38, SNORD115-39, SNORD115-40, SNORD115-41, SNORD115-42, SNORD115-43, SNORD115-44.
- chr15:77,568,970–77,608,888, 1 gene: AC046168.2.
- chr16:67,538,557–67,542,963, 3 genes (within-gene range 0–5): AC027682.5, AC027682.2, AC027682.3.
- chr17:82,400,703–82,401,382, 1 gene (within-gene range 0–3): AC132938.2.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 494 genes in 28 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:58,198–196,334, 4 genes, copy number 8–11 (within-gene range 6–11): AC113430.1, PLEKHG4B, Y_RNA, LRRC14B.
- chr6:32,439,878–32,473,500, 2 genes, copy number 13: HLA-DRA, HLA-DRB9.
- chr6:32,549,940–32,859,851, 19 genes, copy number 15: RNU1-61P, HLA-DRB6, HLA-DRB1, HLA-DQA1, HLA-DQB1, HLA-DQB1-AS1, MTCO3P1, AL662789.1, HLA-DQB3, HLA-DQA2, MIR3135B, HLA-DQB2, HLA-DOB, AL669918.1, TAP2, PSMB8, PSMB8-AS1, PSMB9, TAP1.
- chr6:34,537,802–35,091,406, 15 genes, copy number 11 (within-gene range 3–11): SPDEF, IFITM3P3, ILRUN, RPL7P25, RN7SL200P, AL031577.1, AL451165.2, AL451165.1, AL139100.1, SNRPC, UHRF1BP1, Y_RNA, RNY3P15, TAF11, ANKS1A.
- chr6:35,041,116–35,058,015, 1 gene, copy number 11: AL591002.1.
- chr6:41,636,882–42,050,357, 19 genes, copy number 11 (within-gene range 4–11): MDFI, NPM1P51, TFEB, AL035588.1, PGC, AL365205.4, FRS3, AL365205.1, PRICKLE4, TOMM6, USP49, AL365205.3, AL365205.2, AL160163.1, MED20, Y_RNA, BYSL, CCND3, RNU6-761P.
- chr6:42,224,931–43,075,095, 28 genes, copy number 10: TRERF1, AL591473.1, UBR2, RNU6-890P, PRPH2, ATP6V0CP3, TBCC, BICRAL, RPL7L1, C6orf226, PTCRA, AL035587.2, CNPY3, AL035587.1, RPL24P4, GNMT, PEX6, PPP2R5D, MEA1, KLHDC3, RRP36, AL136304.1, RN7SL403P, CUL7, KLC4, AL355385.2, MRPL2, AL355385.1.
- chr6:43,605,316–43,737,834, 6 genes, copy number 11 (within-gene range 4–11): GTPBP2, MAD2L1BP, RSPH9, MRPS18A, AL136131.1, AL136131.2.
- chr7:16,791,811–17,680,659, 15 genes, copy number 8: AGR2, AC073333.2, AGR3, RAD17P1, AC098592.2, AHR, AC098592.1, AC073332.1, BRWD1P3, Metazoa_SRP, AC019117.3, SNORA63, AC019117.2, AC019117.1, AC006482.1.
- chr7:20,296,637–20,314,512, 1 gene, copy number 7: AC099342.1.
- chr7:54,752,250–55,678,490, 17 genes, copy number 7: SEC61G, SEC61G-DT, AC006971.1, EGFR, EGFR-AS1, ELDR, AC073324.1, CALM1P2, AC073347.1, LANCL2, VOPP1, AC099681.1, AC099681.3, AC099681.2, CDC42P2, TUBBP6, AC091812.1.
- chr7:106,208,167–106,208,267, 1 gene, copy number 7: RNU6-392P.
- chr11:69,147,228–70,189,528, 26 genes, copy number 14–22: AP003071.2, SMIM38, MYEOV, IFITM9P, AP005233.2, AP005233.1, AP000439.2, AP000439.1, AP000439.3, LINC02747, CCND1, LTO1, FGF19, DNAJB6P5, FGF4, FGF3, AP007216.1, AP007216.2, AP003555.2, AP003555.1, LINC02753, LINC02584, RNU6-1175P, ANO1, AP000879.2, ANO1-AS1.
- chr11:71,673,885–71,818,238, 1 gene, copy number 22 (within-gene range 2–22): ALG1L9P.
- chr11:71,711,740–71,997,597, 14 genes, copy number 22: ENPP7P8, AP003498.2, FAM86C1P, ALG1L9P, ZNF705E, DEFB108B, RNA5SP342, DEFB130C, AP002495.1, DEFB131B, OR7E128P, OR7E126P, RNF121, AP002490.2.
- chr11:72,080,331–73,931,114, 71 genes, copy number 8–20 (within-gene range 4–20) (broad region; genes not listed).
- chr12:57,546,026–59,450,772, 51 genes, copy number 15–23 (within-gene range 3–23): KIF5A, PIP4K2C, DTX3, ARHGEF25, AC025165.1, AC025165.6, SLC26A10, B4GALNT1, RPL13AP23, OS9, AC025165.2, AGAP2, AGAP2-AS1, TSPAN31, CDK4, MIR6759, MARCHF9, CYP27B1, METTL1, EEF1AKMT3, AC025165.3, TSFM, AVIL, AC025165.5, RNU6-1083P, AC025165.4, CTDSP2, MIR26A2, AC083805.2, AC083805.1, AC083805.3, ATP23, GIHCG, AC084033.1, RN7SKP65, AC084033.2, LINC02403, AC090643.1, AC090643.2, RPL21P103, AC025578.1, AC020637.1, LINC02388, LRIG3, AC068305.2, RPS6P22, AC068305.1, AC108721.2, AC108721.1, RNU6-279P, RNU6-871P.
- chr14:30,559,158–40,390,547, 172 genes, copy number 7–8 (within-gene range 5–8) (broad region; genes not listed).
- chr14:61,529,128–61,658,696, 4 genes, copy number 8 (within-gene range 6–8): AL355916.3, AL355916.2, LINC01303, AL355916.1.
- chr14:67,819,779–68,730,218, 8 genes, copy number 8–9 (within-gene range 5–9): RAD51B, AL133370.2, AL133370.1, RN7SL706P, RN7SL108P, AL122013.1, PPIAP6, AL121820.3.
- chr14:68,693,656–68,695,734, 1 gene, copy number 9: AL133313.1.
- chr16:67,229,387–67,247,481, 1 gene, copy number 7 (within-gene range 5–7): FHOD1.
- chr17:51,165,435–51,171,744, 1 gene, copy number 7 (within-gene range 4–7): NME2.
- chr19:867,630–893,218, 1 gene, copy number 7: MED16.
- chr19:1,259,384–1,274,880, 2 genes, copy number 7: CIRBP, CIRBP-AS1.
- chr20:37,983,007–38,127,780, 4 genes, copy number 8 (within-gene range 5–8): TTI1, RPRD1B, RN7SL237P, AL031651.1.
- chr20:50,247,643–50,585,241, 8 genes, copy number 8 (within-gene range 5–8): PELATON, LINC01270, LINC01271, RN7SL636P, COX6CP2, PTPN1, RN7SL672P, Y_RNA.
- chr20:53,567,065–53,609,907, 1 gene, copy number 8 (within-gene range 5–8): ZNF217.

Autosomal genes at a single copy (total copy number 1): 480. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
